Surgical pathology report (de-identified scan), TCGA case TCGA-BG-A0VW, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma), tissue source site University of Pittsburgh, specimen TCGA-BG-A0VW-01A (Primary Tumor).

PATIENT HISTORY:

CHIEF COMPLAINT/ PRE-OP/ POST-OP DIAGNOSIS: Endometrial cancer.

LMP DATE: Not provided.

PROCEDURE: Total abdominal hysterectomy, bilateral salpingo-oophorectomy, omentectomy, hernia repair.

SPECIFIC CLINICAL QUESTION: Not provided.

OUTSIDE TISSUE DIAGNOSIS: No.

PRIOR MALIGNANCY: No.

CHEMORADIATION THERAPY: No.

OTHER DISEASES: No.

COMMENT:

Evaluation of endometrial tumor is limited by autolytic changes.

Immunohistochemical stains were performed for evaluation of this tumor and the presence of lymphovascular space invasion (please see microscopic description for complete report).

Companion pelvic wash is negative for tumor

Pathologic stage: T1aNoMx, FIGO - IA (current classification).

MICROSCOPIC:**Antibody/Antigen**

P16

P53

P63

CD31

D2-40

CD34

Result

Patchy positive.

Negative

Negative

Positive in endothelial, lymphatic and vascular channels.

Positive in endothelial, lymphatic and vascular channels.

Positive in endothelial, lymphatic and vascular channels.

1CD-0-3

adenocarcinoma, endometrioid, NOS 8380/3

Site: endometrium c54.1

5/1/11

Utilizing formalin-fixed (8-96 hour range), paraffin embedded tissue, immunohistology is performed with the following selected antibodies and designated antibody clone(s), directed against the following antigenic target(s), with adequate positive and negative internal and external controls. Antibodies are optimized appropriate for fixation times.

ANTIBODY**CLONE****TARGET ANTIGEN****VENDOR**

p16

P53

p63

CD 31

D2-40

CD 34

16P04(JC2)

DO-7

4A4 + Y4A3

JC70

D2-40

QBEnd/10

HPV surrogate

Serous Carcinoma

Myoepithelial cells

endothelium

Lymphatic Endothelium

endothelium

Microscopic examination substantiates the above diagnosis.

The following statement applies to all immunohistochemistry, in situ hybridization (ISH & FISH), molecular anatomic pathology, and immunofluorescence testing:

The testing was developed and its performance characteristics determined by the i required by the CLIA '88 regulations. The testing has not been cleared or approved for the specific use by the U.S. Food and Drug Administration, but the FDA has determined such approval is not necessary for clinical use.

This laboratory is certified under the Clinical Laboratory Improvement Amendments of 1988 ("CLIA") as qualified to perform high-complexity clinical testing. Pursuant to the requirements of CLIA, ASP's used in this laboratory have been established and verified for accuracy and precision. Additional information about this type of test is available upon request.

CASE SYNOPSIS:**SYNOPTIC - PRIMARY UTERINE ENDOMETRIAL TUMORS: HYSTERECTOMY SPECIMENS****TUMOR TYPE:**

Endometrioid adenocarcinoma, NOS

HISTOLOGIC GRADE (epithelial neoplasm) [combined architectural and nuclear]:

Well differentiated (FIGO 1)

Well differentiated

Grade 2

ARCHITECTURAL GRADE:**NUCLEAR GRADE:****TUMOR SIZE:**

Maximum dimension: 2.0 cm

PERCENT OF ENDOMETRIAL SURFACE INVOLVEMENT:

Anterior endomyometrium: 10 %, Posterior endomyometrium: 30 %

DEPTH OF INVASION:**

Less than 1/2 thickness of myometrium

ANGIOLYMPHATIC INVASION:

No

OTHER:

(epithelial, smooth muscle, others), Leiomyoma

LYMPH NODES POSITIVE:

Number of lymph nodes positive: 0

LYMPH NODES EXAMINED:

Total number of lymph nodes examined: 10

T STAGE, PATHOLOGIC:

pT1b

N STAGE, PATHOLOGIC:

pN0

M STAGE, PATHOLOGIC:

pMX

FIGO STAGE:

IB

Source: NCI Genomic Data Commons file 3fbcbcab-bb31-4924-b897-a291bb0594de (TCGA-BG-A0VW.7663D410-13EC-4A5B-B655-F7DCCC9C8E8D.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).